Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JL-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

Patient ID – Sample ID

(A) LEFT INGUINAL SUPERFICIAL AND FEMORAL LYMPH NODES, EXCISION:
CONSISTENT WITH METASTATIC MELANOMA.
Tumor measures 10 x 20 x 35 mm in gross description.
Eight definite lymph nodes negative for metastatic melanoma.

COMMENT

It is possible that this metastatic focus of melanoma represents a completely effaced lymph node and thus one of nine lymph nodes would be positive. Immunohistochemistry will be performed to confirm this diagnosis and reported as an addendum. No pigment is noted in tumor cells.

Entire report and diagnosis completed by

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, inguinal
C 77.4
JW 7/24/11

GROSS DESCRIPTION

(A) LEFT INGUINAL SUPERFICIAL, TUMOR AND LYMPH NODES - A 23.0 x 7.5 x 2.0 cm portion of yellow, lobulated fibroadipose tissue. A 3.5 x 2.0 x 1.0 cm solid, gray, poorly circumscribed mass is present. Nine lymph nodes ranging from 0.6 to 1.0 cm are identified.

SECTION CODE: A1, A2, tumor, representative sections; A3, one possible lymph node; A4, four possible lymph nodes; A5, two possible lymph nodes; A6, one possible lymph node, bisected; A7, A8, one possible lymph node, serially sectioned; A9, A10, one possible lymph node, serially sectioned. Tissue from tumor submitted to tissue bank.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

3. These tests have not been

Released by: UUID:9D32B522-7FD4-47F6-9302-934185AEAD0B

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

Addendum completed by

COMMENT

An immunohistochemical study is performed for pan-melanoma cocktail (HMB-45 and anti-MART 1) showing diffuse reactivity within the tumor cells and strongly supporting the diagnosis of melanoma.

Released by

-----END OF REPORT-----

Source: NCI Genomic Data Commons file d324c5cd-9c97-4738-8a89-14a5b294992c (TCGA-D3-A2JL.9D32B522-7FD4-47F6-9302-934185AEAD0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).